Surgical pathology report (de-identified scan), TCGA case TCGA-FZ-5923, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-FZ-5923-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: PANCREAS, UNCINATE, BIOPSY –
ADENOCARCINOMA (see comment).

PART 2: GALLBLADDER, CHOLECYSTECTOMY –
CHRONIC CHOLECYSTITIS.

PART 3: GASTRODUODENAL LYMPH NODE, EXCISION –
ONE (1) BENIGN LYMPH NODE.

PART 4: PANCREAS, HEAD, BIOPSY –
ADENOCARCINOMA (see comment).

PART 5: STOMACH, DUODENUM, PANCREAS, BILE DUCT, WHIPPLE RESECTION –
A. INVASIVE WELL DIFFERENTIATED ADENOCARCINOMA OF THE HEAD OF THE PANCREAS (3.8 CM).
B. THE CARCINOMA INVADES BEYOND THE PANCREAS TO INVOLVE THE PERIPANCREATIC SOFT TISSUE AND DUODENUM.
C. METASTATIC ADENOCARCINOMA IS PRESENT IN ONE OF THIRTEEN (1/13) PERIPANCREATIC LYMPH NODES.
D. PROXIMAL GASTRIC, DISTAL DUODENAL, BILE DUCT, PANCREATIC, RETROPERITONEAL AND VASCULAR GROOVE MARGINS ARE NEGATIVE FOR TUMOR.
E. PANCREATIC INTRAEPITHELIAL NEOPLASIA, GRADE 3 (PANIN-3).
F. PATHOLOGIC STAGE; pT3, N1, M1 (SEE PART 6).

PART 6: TRANSVERSE MESOCOLON, EXCISION –
A. METASTATIC ADENOCARCINOMA INVOLVING FIBROADIPOSE TISSUE.
B. ONE (1) BENIGN LYMPH NODE.

PART 7: TRANSVERSE MESOCOLON, LYMPH NODE, EXCISION –
ONE (1) BENIGN LYMPH NODE.

COMMENT:

The biopsies of the pancreas are diagnostic of adenocarcinoma in comparison to the main resection specimen which shows a well-differentiated adenocarcinoma with features similar to those seen in the biopsies.

SYNOPTIC DATA - PRIMARY PANCREAS (EXOCRINE) TUMORS

----- MACROSCOPIC -----

SPECIMEN TYPE: Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy
TUMOR SITE: Pancreatic head
TUMOR SIZE: Greatest dimension: 3.8 cm
Additional dimensions: 3.2 x 2.5 cm
OTHER ORGANS RESECTED: Gallbladder

----- MICROSCOPIC -----

HISTOLOGIC TYPE: Ductal adenocarcinoma
HISTOLOGIC GRADE: G1
PATHOLOGIC STAGING (pTNM): pT3
pN1a
Number of lymph nodes examined: 13
Number of lymph nodes involved: 1
pM1
MARGINS: Site(s): transverse mesocolon (part 6)
Common bile duct margin uninvolved
Pancreatic parenchymal margin uninvolved
Uncinate process/retroperitoneal margin uninvolved
SMV/portal vein notch margin uninvolved
Proximal duodenal/gastric margin uninvolved
Distal duodenal margin uninvolved
Distance of invasive carcinoma from closest margin: 2 mm
Margin: vascular groove

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

PERINEURAL INVASION: Present
ADDITIONAL PATHOLOGIC FINDINGS: Present

Pancreatic intraepithelial neoplasia (highest grade: PanIN 3)

Source: NCI Genomic Data Commons file c1a12bca-94c8-4795-8145-fdea73497810 (TCGA-FZ-5923.C21958E8-38CC-4D5F-A1A3-A1E068FDE5D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).